Surgical pathology report (de-identified scan), TCGA case TCGA-F2-7276, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site UNC, specimen TCGA-F2-7276-01A (Primary Tumor).

[page 1 of 7]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

FSA: Liver, Segment 4, excision

- Liver parenchyma with macrovesicular steatosis (approximately 5%) and bile stasis
- Benign bile duct proliferation
- No evidence of malignancy

FSB: Right diaphragm, excision

- Fibroadipose tissue with scattered chronic inflammation
- No evidence of malignancy

FSC: Liver, Segment 7, excision

- Liver parenchyma with macrovesicular steatosis (approximately 5%) and bile stasis and bile duct proliferation
- No evidence of malignancy

FSD: Liver, Segment 2, excision

- Fragment of benign cyst wall
- No evidence of malignancy

FSE: Liver, Segment 3, excision

- Fragment of benign cyst wall
- Hyalinized nodule
- No evidence of malignancy

FSF: Common bile duct margin, removal

- Fibrous tissue with scattered biliary ducts and chronic inflammation
- No evidence of malignancy

FSG: Pancreatic duct margin, removal

- Fibrous tissue with scattered pancreatic ductules
- No evidence of malignancy

H: Gallbladder, cholecystectomy

- Chronic cholecystitis
- No evidence of malignancy

I: Lymph node, portal, removal

- One lymph node negative for malignancy (0/1)

J: Lymph node, common hepatic, removal

- One lymph node positive for metastatic adenocarcinoma (1/1)

[page 2 of 7]
K: Pancreas, stomach and small bowel, partial
pancreaticoduodenectomy

Tumor Histologic Type: Ductal adenocarcinoma

Histologic grade: Well-differentiated

Tumor size: 5.5 cm

Tumor site: Head with extension into body

Tumor focality: Unifocal

Microscopic extent of invasion:

Peripancreatic soft tissues: Present (K8)

Duodenum: Absent

Ampulla: Present (K6)

Other organs or structures: N/A

Lymphovascular Invasion: Present (K16)

Perineural Invasion: Present (K11, K12)

Margins:

Pancreatic neck: Negative

Bile duct: Negative

Posterior pancreatic surface (deep radial margin): Negative but
close; <1mm (K11)

Peripancreatic soft tissues: Negative but close; < 1mm (K14)

Proximal (gastric): Negative

Distal (duodenal): Negative

Regional lymph nodes: (all specimens except part L)

Total number with metastasis: 8

Total number examined: 16

Additional pathologic findings: Acute serositis

Diagnosis of other organs or structures: n/a

AJCC PATHOLOGIC TNM STAGE: pT3 pN1

Note: This pathologic stage assessment is based on information
available at the time of this report, and is subject to change
pending clinical review and additional information.

[page 3 of 7]
L: Mesentery, colon, removal

- One lymph node positive for metastatic adenocarcinoma (1/1)

Intraoperative Consult Diagnosis:

A frozen section consultation was requested by Dr. on _____ at _____
from _____

FSA1: Liver, Segment 4, biopsy

- Bile duct proliferation, benign

FSB1: Diaphragm, right, biopsy

- Fibroadipose tissue with inflammation and atypical cells. No definite metastatic carcinoma.

FSC1: Liver, Segment 7, biopsy

- Bile duct proliferation with atypia
- Marked inflammation and cholestasis
- No definite metastatic carcinoma

FSD1: Liver, Segment 2, biopsy

- No tumor seen

FSE1: Liver, Segment 3, biopsy

- Bile duct proliferation, no tumor seen

FSF1: Common bile duct, margin

- No carcinoma identified

FSG1: Pancreatic duct margin

- No carcinoma identified

Drs. and additional help was received from ; the diagnosis was delivered to the requesting physician at _____

Frozen Section Pathologist:

Clinical History:

-year-old with a clinical diagnosis of pancreatic cancer.

Gross Description:

Received are twelve appropriately labeled containers. Containers A-G are received fresh for frozen section.

[page 4 of 7]
Container A is additionally labeled "liver, Segment 4." The container holds a yellow cassette that is additionally labeled FSA1." At frozen section the specimen was described as measuring 7 x 4 x 2 mm and appeared as a red/tan soft tissue fragment. The specimen was totally submitted in block FSA1,

Container B is additionally labeled "right diaphragm." The container holds one yellow cassette that is additionally labeled FSB1." At frozen section the specimen was described as measuring 2 x 2 mm and appeared as a red/tan soft tissue fragment. The specimen was totally submitted as FSB1,

Container C is additionally labeled "Segment 7." The container holds one yellow cassette that is additionally labeled FSC1." At frozen section the specimen was described as three fragments that measured 1 x 0.5 x 0.2 cm in aggregate. The specimen was totally submitted in block FSC1,

Container D is additionally labeled "Segment 2." The container holds one yellow cassette that is additionally labeled FSD1." At frozen section the specimen was described as three fragments of soft tissue that measured 1 x 0.2 x 0.2 cm in aggregate. The specimen was totally submitted in block FSD1,

Container E is additionally labeled "Segment 3." The container holds one yellow cassette that is additionally labeled FSE1." At frozen section the specimen was described as measuring 1 x 1 x 0.2 cm and appeared as a liver fragment with a nodule at the center (2 x 2 mm and white). The specimen was totally submitted in block FSE1,

Container F is additionally labeled "common bile duct margin." The container holds one yellow cassette that is additionally labeled FSF1." At frozen section the specimen was described as measuring 2.4 x 1.3 x 0.4 cm and appeared as a pink/tan soft tissue fragment. The specimen was totally submitted into block FSF1,

Container G is additionally labeled "pancreatic duct margin." The container holds one yellow cassette that is additionally labeled FSG1." At frozen section the specimen was described as measuring 3 x 3 x 2 mm and appeared as a red/tan soft tissue fragment that was totally submitted into block FSG1,

[page 5 of 7]
Container H is additionally labeled "gallbladder."

Previously opened: No

Measurements: 7 x 3 x 2.4 cm

External surface: Appears pink and smooth with no evidence of fibrofatty adhesions

Wall thickness: 0.2 cm uniformly

Mucosa: Patchy green color with hemorrhagic appearance; texture appears velvety

Stones present: No

Other comments: None

Block #: H1, cross section of cystic duct and longitudinal section of gallbladder wall

Container I is additionally labeled "portal node." The container holds one piece of fibroadipose tissue that measures 1.5 x 0.5 x 0.4 cm. The specimen has been bisected and totally submitted into block I1,

Container J is additionally labeled "common hepatic node." The container holds one piece of fibroadipose tissue that measures 1.4 x 1.2 x 1.0 cm. The specimen has been bisected and totally submitted in block J1,

Container K is additionally labeled "pancreatic duodenectomy, short stitch=pancreatic duct, short proline=portal vein margin, long stitch=common bile duct, long proline=uncinate margin".

Specimen fixation: Formalin

Specimen type: Pancreaticoduodenectomy

Organs received (Whipple Specimen): Duodenum 17 x 2.2 cm, stomach 3.2 x 6 x 1 cm, pancreas 3 x 2.3 x 2 cm.

Orientation: This specimen has been previously inked as follows: yellow/common bile duct, blue/pancreatic margin, black/uncinate, green/pancreatic body, red/portal vein; short stitch = pancreatic duct, short stitch = portal vein margin, long stitch = common bile duct, long stitch = uncinate margin.

Tumor location: Head of pancreas

Gross appearance of tumor: The mass is within the head and body of the pancreas; the mass is ill-defined and appears yellow/tan with infiltrative nodular growth; the mass is solid with no areas of apparent necrosis or hemorrhage.

[page 6 of 7]
Tumor dimensions: 5.5 x 3 x 3 cm

Extent of invasion:

Confined/non confined to the pancreas: Grossly confined

Involvement of the ampulla: Absent

Involvement of the duodenum: Absent

Involvement of the bile duct: Absent

Involvement of adjacent vessels: The lesion is close to the location of the portal vein; there is indefinite involvement by gross examination.

Spleen (if applicable): Not applicable

Gallbladder (if applicable): Not applicable

Stomach (if applicable): Absent

Surgical margins:

Pancreatic body: Negative, 0.2 cm away

Uncinate (Retroperitoneal): Negative, 0.1 cm away

Common Bile duct: Negative, 0.6 cm away

Proximal margin (stomach): (Stomach), negative, 9.5 cm away

Distal margin (duodenum): (Duodenum), negative, 12.5 cm away

Peripancreatic soft tissues: Negative, 0.4 cm away

Lymph nodes: There are 5 candidate lymph nodes identified. Two candidate lymph nodes are identified between the duodenum and the uncinate. The smallest measures 0.4 x 0.3 x 0.3 cm and the largest measures 1 x 0.5 x 0.3 cm. Three candidate lymph nodes are identified in the fatty tissue surrounding the stomach. These perigastric lymph nodes range in size from 0.2 x 0.2 x 0.2 cm to 0.3 x 0.3 x 0.3 cm.

Other remarkable findings: None

[page 7 of 7]
Digital photograph taken: No

Tissue submitted for special investigation: Yes

Block Summary:

Inking: : yellow/common bile duct, blue/pancreatic margin,
black/uncinate, green/pancreatic body

K1-K2 - Proximal margin, en face

K3-K4 - Distal margin, en face

K5 - Portal vein margin, en face

K6-K10 - Ampulla of Vater, perpendicular section (common bile
duct located in K10)

K11-K14 - Uncinate margin, perpendicular sections (one section
per cassette)

K15-K23 - Pancreatic body margin, perpendicularly sectioned (one
section every 2 cassettes K17-K22)

K24-K25 - Periuncinate lymph nodes, bisected (one lymph node per
cassette)

K26 - Three candidate perigastric lymph nodes (not bisected)

K27 - Duodenum and tumor

K28 - Representative sections of normal duodenum

K29 - Two representative sections of central tumor

Container L is additionally labeled "colon mesentery." The
container holds one piece of tan/yellow fibroadipose tissue that
measures 0.7 x 0.6 x 0.3 cm. The specimen has been bisected and
submitted in block L1,

Source: NCI Genomic Data Commons file 8ba281b3-0dfe-44ad-99d4-8ae50ef8e203 (TCGA-F2-7276.35F25A99-E6C7-4748-8BE7-EA4867577A1B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).